Somatic mutation profile of tumor specimen MP2PRT-PAPUSF-TMP1-A (aliquot MP2PRT-PAPUSF-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPUSF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,185 days).
Specimen MP2PRT-PAPUSF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcb90a9d-651b-42e7-9241-1c1ece0eb4f8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPUSF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPUSF-NB1-A-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/20a33daf-cbeb-4254-8dcf-2aab9ceb7c9c

The open-access MAF lists 12 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG10B | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 59/328 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372347662; called by muse, mutect2, varscan2
- ATCAY | c.401G>A p.S134N | Missense Mutation (SNP) | VAF 105/523 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.759); catalogued as rs772977190; called by muse, mutect2, varscan2
- CEP170B | c.2692G>A p.A898T (on ENST00000453495; = p.A827T on NM_015005.3) | Missense Mutation (SNP) | VAF 129/620 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as rs758620472; called by muse, mutect2, varscan2
- DCLK1 | c.146C>T p.T49M | Missense Mutation (SNP) | VAF 50/460 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs373107227; called by muse, mutect2, varscan2
- MYH8 | c.3508C>T p.R1170W | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67975050; called by muse, mutect2, varscan2
- ADAMTS19 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 149/626 reads (24%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CIT | c.1589A>G p.Q530R | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IKZF1 | c.475A>T p.N159Y | Missense Mutation (SNP) | VAF 138/497 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PSMC1 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 42/325 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SBF2 | c.2045_2046insGGACACC p.S683Dfs*22 | Frame Shift Ins (INS) | VAF 37/294 reads (13%) | called by mutect2, pindel, varscan2
- DACH2 | c.894C>A p.T298= | Silent (SNP) | VAF 118/494 reads (24%) | catalogued as rs1427152412; called by muse, mutect2, varscan2
- EPHB3 | c.1191G>A p.E397= | Silent (SNP) | VAF 74/401 reads (18%) | called by muse, mutect2, varscan2
